Gene-level copy-number profile of tumor specimen BLGSP-71-21-00186-01A from CGCI case BLGSP-71-21-00186, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 27.7 years (10,131 days).
Specimen BLGSP-71-21-00186-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Mesenteric; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 95674a3e-03e9-497e-8826-6bbeec979518.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-21-00186-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/3174f809-0c87-42b7-9ba9-9e811bcef8ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 4,094; copy number 2: 47,017; copy number 3: 7,679; copy number 4: 68; copy number 5: 6; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr13:36,819,222–36,829,104, 1 gene: RFXAP.
- chr13:36,849,366–36,850,046, 1 gene (within-gene range 0–1): SMAD9-IT1.
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–1): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–105,903,631, 29 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,623,339–18,653,617, 3 genes, copy number 5: SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,773,665–18,861,049, 4 genes, copy number 5–6 (within-gene range 4–9): GGT3P, AC008132.2, E2F6P1, AC008132.1.

Autosomal genes at a single copy (total copy number 1): 1,248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
